Somatic mutation profile of tumor specimen MMRF_2461_1_BM_CD138pos (aliquot MMRF_2461_1_BM_CD138pos_T1_KHS5U_L11622) from MMRF case MMRF_2461, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 87.3 years (31,872 days).
Specimen MMRF_2461_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bf996e1-4b2c-43e5-bc69-19bda1d21de8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2461_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2461_1_PB_Whole_C3_KHS5U_L11623; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c850407-dba9-494e-bef3-67a5f306f5a0

The open-access MAF lists 149 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 39, Silent 21, Intron 15, 5'UTR 6, 3'Flank 5, Frame Shift Del 3, 5'Flank 3, Nonsense Mutation 3, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UBTF | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs1555582065; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCC2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs200570593, COSV100965602; called by muse, mutect2, varscan2
- ALDH8A1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs765559483; called by muse, mutect2, varscan2
- ANKFN1 | c.3428C>T p.P1143L (on ENST00000653862; = p.P996L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs903395229, COSV101633512, COSV101633536; called by muse, mutect2, varscan2
- CCDC60 | c.1089G>T p.Q363H | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV59547643; called by muse, mutect2, varscan2
- CPXM1 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 139/312 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV66045994; called by muse, mutect2, varscan2
- CTU1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1457108245; called by muse, mutect2
- DUOX2 | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.516); catalogued as rs779289206; called by muse, mutect2, varscan2
- DUSP11 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55595743; called by muse, mutect2
- EPHB4 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs768820666, COSV62268463; called by muse, mutect2, varscan2
- FBXL13 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs533885154, COSV50864434; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370193821; called by muse, varscan2
- IGHV2-70 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs377373222; called by muse, varscan2
- IGHV2-70 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs10144703; called by muse, varscan2
- IGHV2-70D | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1395593521; called by muse, varscan2
- KMT2C | c.12334A>G p.S4112G | Missense Mutation (SNP) | VAF 201/630 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1290269784; called by muse, mutect2, varscan2
- MYH3 | c.4879G>T p.E1627* | Nonsense Mutation (SNP) | VAF 47/114 reads (41%) | catalogued as COSV56861514; called by muse, mutect2, varscan2
- NEK1 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV71455237; called by muse, mutect2, varscan2
- OR52L1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV59986026, COSV59988219; called by muse, mutect2, varscan2
- PLPPR1 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66454371; called by muse, mutect2
- PRAMEF19 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1391863549; called by muse, mutect2, varscan2
- RASGRF2 | c.965T>C p.L322S | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54127659; called by muse, mutect2, varscan2
- RTL9 | c.3862C>T p.R1288W | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1446494457, COSV71825438; called by muse, mutect2, varscan2
- SH2D4B | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as rs920828247; called by muse, mutect2, varscan2
- ANKAR | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARNT2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CCN4 | c.131del p.S44Yfs*69 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- COX4I1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DTWD1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHD4 | c.513C>G p.G171= | Splice Region (SNP) | VAF 30/284 reads (11%) | called by muse, mutect2, varscan2
- FGD3 | c.1495A>T p.I499F | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, mutect2
- GBF1 | c.584+2T>A p.X195_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- GRAMD1B | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HHIPL1 | c.771C>A p.H257Q | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV1-5 | chr2:88947299 GGA>CCCT | Missense Mutation (INS) | VAF 37/55 reads (67%) | called by pindel, varscan2*
- IGLV3-22 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 99/218 reads (45%) | called by muse, varscan2
- IQCJ-SCHIP1 | c.213C>G p.S71R | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- KAT5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- KCNF1 | c.1457_1464del p.H486Pfs*24 | Frame Shift Del (DEL) | VAF 71/214 reads (33%) | called by mutect2, pindel, varscan2
- KDM4C | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- KIFC3 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- LRRC1 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 53/525 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MBTPS2 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- NKTR | c.3011A>C p.K1004T | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- NKX2-8 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- NLRP7 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- OLFM1 | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PLEC | c.3595A>T p.T1199S (on ENST00000322810 / NM_201380.4; = p.T1089S on NM_000445.5) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA4 | c.1195A>T p.T399S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPP2R1B | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- PRDM11 | c.1349G>T p.R450L (on ENST00000530656 / NM_001359633.1; = p.R416L on NM_001256695.1) | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN3A | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SLC2A9 | c.180_183del p.L61Rfs*17 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by pindel, varscan2
- SOX1 | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SOX10 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV6-7 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, varscan2
- USH2A | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- USP34 | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ZNF880 | c.1613A>T p.H538L | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMC4 | c.816T>C p.N272= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as rs929289705; called by muse, mutect2
- B3GNT3 | c.1029G>A p.V343= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- BTG1 | c.138G>A p.E46= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs200623021, COSV55460075; called by muse, mutect2, varscan2
- CLIP2 | c.1746C>T p.R582= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as rs782382338, COSV56274513; called by muse, mutect2, varscan2
- DUSP2 | c.330G>A p.L110= | Silent (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- FANCC | c.477T>G p.S159= | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- FRAS1 | c.3522C>T p.N1174= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs548358301, COSV53587448; called by muse, mutect2, varscan2
- HNRNPUL2 | c.58C>T p.L20= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1355956072; called by muse, mutect2
- IGHD2-2 | c.15G>A p.*5= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs556550423; called by muse, mutect2, varscan2
- KLK12 | c.618T>C p.C206= | Silent (SNP) | VAF 73/263 reads (28%) | catalogued as rs370146789; called by muse, mutect2, varscan2
- NIBAN2 | c.1446C>T p.Y482= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs144943149, COSV104394200; called by muse, mutect2, varscan2
- OR10G2 | c.372C>T p.A124= | Silent (SNP) | VAF 82/232 reads (35%) | catalogued as rs1307454854; called by muse, varscan2
- PCDHGC5 | c.93T>C p.L31= | Silent (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- PLXNA1 | c.210C>T p.R70= | Silent (SNP) | VAF 81/357 reads (23%) | called by muse, varscan2
- PPP1R37 | c.390C>T p.V130= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- TBC1D5 | c.1263G>T p.V421= | Silent (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- TCN1 | c.330A>G p.E110= | Silent (SNP) | VAF 104/240 reads (43%) | called by muse, mutect2, varscan2
- TET1 | c.6087T>C p.A2029= | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2
- TFAP2B | c.877T>C p.L293= | Silent (SNP) | VAF 76/225 reads (34%) | called by muse, mutect2, varscan2
- ZFP42 | c.165C>T p.C55= | Silent (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- ZNF254 | c.1887C>A p.P629= | Silent (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- AGAP1 | c.*1728C>A | 3'UTR (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25169088 G>A | 3'Flank (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- ATP2C1 | chr3:130894498 T>G | 5'Flank (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- C19orf12 | chr19:29702276 G>A | 3'Flank (SNP) | VAF 22/207 reads (11%) | catalogued as rs1165202242; called by muse, mutect2, varscan2
- CACNA2D4 | c.2922-124G>A | Intron (SNP) | VAF 39/81 reads (48%) | catalogued as rs1325712975; called by muse, mutect2, varscan2
- CACNB4 | c.*3986C>A | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CALHM5 | c.*4871T>C | 3'UTR (SNP) | VAF 24/61 reads (39%) | catalogued as rs1450976914; called by muse, varscan2
- CARD11 | c.*266C>T | 3'UTR (SNP) | VAF 83/324 reads (26%) | catalogued as rs1182948864; called by muse, mutect2, varscan2
- CCDC92 | c.-59-964C>T | Intron (SNP) | VAF 113/231 reads (49%) | called by muse, mutect2, varscan2
- CDC14A | c.*845del | 3'UTR (DEL) | VAF 11/56 reads (20%) | catalogued as rs940405832; called by mutect2, varscan2
- CFAP20DC | c.198-16927G>T | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2
- CNTNAP2 | c.*3492C>T | 3'UTR (SNP) | VAF 84/158 reads (53%) | catalogued as rs1554433512; called by muse, mutect2, varscan2
- CTNNA2 | c.102+36028del | Intron (DEL) | VAF 52/158 reads (33%) | called by mutect2, pindel, varscan2
- DNAJB6 | c.691+211G>T | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- EEF1A2 | c.144+49C>A | Intron (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691023 del T | 3'Flank (DEL) | VAF 27/91 reads (30%) | catalogued as rs920483656; called by mutect2, varscan2
- EMC3 | c.657+144C>G | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- EPRS1 | c.-56C>T | 5'UTR (SNP) | VAF 31/174 reads (18%) | called by muse, mutect2, varscan2
- FAM133A | c.*336A>C | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- FAM180B | c.*133G>A | 3'UTR (SNP) | VAF 53/331 reads (16%) | called by muse, mutect2, varscan2
- FAM83A | c.*1877A>G | 3'UTR (SNP) | VAF 122/290 reads (42%) | called by muse, varscan2
- GNAZ | c.*161T>A | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- GNE | c.*1870T>G | 3'UTR (SNP) | VAF 51/91 reads (56%) | called by muse, mutect2, varscan2
- H2BC21 | c.*344C>G | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- IHO1 | c.532+754C>T | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2
- KLHL21 | c.*2305G>A | 3'UTR (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- LANCL3 | c.*1369A>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- LEF1 | c.213+982C>T | Intron (SNP) | VAF 93/216 reads (43%) | called by muse, mutect2, varscan2
- LHX5 | chr12:113471881 G>A | 5'Flank (SNP) | VAF 64/125 reads (51%) | called by muse, mutect2, varscan2
- LOX | c.*2559G>A | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- LZTS1 | c.*2370C>A | 3'UTR (SNP) | VAF 86/172 reads (50%) | called by mutect2, varscan2
- MAGIX | chrX:49166738 G>A | 3'Flank (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- MEIS2 | c.1147+408G>A | Intron (SNP) | VAF 129/798 reads (16%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+3669T>C | Intron (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- MTCL1 | c.3561+2504G>A | Intron (SNP) | VAF 80/114 reads (70%) | called by muse, mutect2
- MYO1E | c.-25A>G | 5'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, varscan2
- NETO1 | c.469+23944A>C | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- NHLRC2 | c.*3367C>T | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- NME5 | c.*493A>T | 3'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, varscan2
- NXPE3 | c.*1343G>A | 3'UTR (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1130T>G | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, varscan2
- PCDH17 | c.*255del | 3'UTR (DEL) | VAF 7/34 reads (21%) | catalogued as rs374477632; called by pindel, varscan2
- PGM3 | c.*3848C>A | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by mutect2, varscan2
- PKNOX1 | c.*2497T>G | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2
- PLAG1 | c.*4709G>A | 3'UTR (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- POLR1E | chr9:37486005 T>C | 5'Flank (SNP) | VAF 101/196 reads (52%) | catalogued as rs369689056; called by muse, mutect2, varscan2
- PPM1A | c.*5500C>A | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- RFX4 | c.44-7509G>A | Intron (SNP) | VAF 28/91 reads (31%) | catalogued as rs754869980; called by muse, mutect2, varscan2
- RIPPLY1 | c.*102T>C | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- RNF167 | c.*22C>T | 3'UTR (SNP) | VAF 4/71 reads (6%) | catalogued as COSV52590370; called by muse, mutect2
- RSPO2 | c.*601T>C | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- SARM1 | c.*1097T>G | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- SCML2 | c.*647T>C | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- SERPINA7 | c.*169C>T | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*305G>A | 3'UTR (SNP) | VAF 5/105 reads (5%) | catalogued as COSV66152606; called by muse, mutect2
- SLC5A10 | c.*574G>A | 3'UTR (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- SPAST | c.-113G>A | 5'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- TEKT1 | c.*1793C>T | 3'UTR (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- TMEM40 | chr3:12734638 A>T | 3'Flank (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- TMEM50B | c.*1366C>G | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- UBASH3A | c.*264C>A | 3'UTR (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- WDR7 | c.*498A>G | 3'UTR (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- ZBBX | c.*343T>G | 3'UTR (SNP) | VAF 83/144 reads (58%) | called by muse, mutect2, varscan2
- ZNF37A | c.-9C>T | 5'UTR (SNP) | VAF 61/371 reads (16%) | catalogued as rs552565802; called by muse, mutect2, varscan2
- ZNF391 | c.*1937C>T | 3'UTR (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- ZNF812P | n.544+1234T>A | Intron (SNP) | VAF 13/55 reads (24%) | catalogued as rs1295269707; called by muse, mutect2
- ZP4 | c.-139A>G | 5'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ZP4 | c.-140C>A | 5'UTR (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
